Somatic mutation profile of tumor specimen TCGA-4V-A9QT-01A (aliquot TCGA-4V-A9QT-01A-11D-A423-09) from TCGA case TCGA-4V-A9QT, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type B1, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 79.3 years (28,951 days).
Specimen TCGA-4V-A9QT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ff0fc20-1a33-4586-9b60-413499158de7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4V-A9QT-10A (Blood Derived Normal), aliquot TCGA-4V-A9QT-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3e98523-bef6-4007-9ba7-eb47e60bdc3d

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIRREL2 | c.1192C>T p.P398S | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.335); called by muse, mutect2
- MYO15A | c.4768T>A p.Y1590N | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- SLITRK5 | c.2622C>T p.L874= | Silent (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
